Surgical pathology report (de-identified scan), TCGA case TCGA-28-1760, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-1760-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

- A. SITE #1 (RIGHT OCCIPITAL CRANIOTOMY):
- Unremarkable gray and white matter
- B. SITE #2 (RIGHT OCCIPITAL CRANIOTOMY):
- Glioblastoma multiforme, WHO grade IV
- C. NCI RESEARCH PROTOCOL:
- Glioblastoma multiforme with approximate 10% necrosis
- D. NCI RESEARCH PROTOCOL:
- Glioblastoma multiforme without apparent necrosis
(One piece showing gray matter with few infiltrating tumor cells)
- E. NCI RESEARCH PROTOCOL:
- Glioblastoma multiforme without apparent necrosis
(One piece showing gray matter with few infiltrating tumor cells)
- F. NCI RESEARCH PROTOCOL:
- Glioblastoma multiforme without apparent necrosis
- G. NCI RESEARCH PROTOCOL:
- Glioblastoma multiforme with approximate 5% necrosis
- H. NCI RESEARCH PROTOCOL:
- Glioblastoma multiforme with less than 5% necrosis
- I. BRAIN TUMOR (RIGHT OCCIPITAL CRANIOTOMY):
- Glioblastoma multiforme, WHO grade IV
- J. SITE #3 (RIGHT OCCIPITAL CRANIOTOMY):
- Glioblastoma multiforme, WHO grade IV
- K. BRAIN TUMOR (RIGHT OCCIPITAL CRANIOTOMY):
- Glioblastoma multiforme, WHO grade IV

COMMENT: Immunostain for MGMT is considered to be positive (30% of tumor cells positive). The majority of tumor cells are immunoreactive for PTEN and MAPK. Both laminin beta 1 and laminin beta 2 are moderately up-regulated (see note).

Patient Case(s):

[page 2 of 3]
PATIENT:

PATH #:

Note:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar. Hence, the 30% result in this case may suggest the possibility of a relatively diminished response to Temodar.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas. Hence, retained expression of PTEN in this case may suggest the possibility of a relatively favorable prognosis.

Presence of activated (phosphorylated) p42/44 mitogen-activated protein kinase (pMAPK) in glioblastoma multiforme has been shown to be associated with a relative resistance to radiation therapy. Hence, a high percentage of tumor cells immunoreactive to pMAPK antibody (although a cut-off point has not been well established yet at the moment) in this case may suggest the possibility of a relative resistance to radiation therapy.

Recent studies have shown an adverse prognostic significance of increased laminin $\beta 1$ (laminin-8) and decreased laminin $\beta 2$ (laminin-9) expression predicting a worse survival of patients with high grade gliomas. et al: Association between laminin-8 and glial tumor grade, recurrence, and patient survival. Cancer. Hence, elevated expression of laminin $\beta 1$ and $\beta 2$ in this tumor may suggest the tumor aggressiveness intermediate between the $\beta 1$ (or normal)/ $\beta 2$ (or normal) (the most favorable prognosis) and $\beta 1/\beta 2$ (the least favorable prognosis).

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents

HISTORY: Right occipital brain tumor

MICROSCOPIC:

See diagnosis.

IMMUNOSTAINS:

MGMT, PTEN, MAPK, laminin beta 1 and laminin beta 2 (K1)

GROSS:

A. SITE #1

Labeled with the patient's name, labeled "site #1", and received in formalin is a 0.4 x 0.3 x 0.3 cm soft pink-tan tissue fragment. The specimen is entirely submitted.

A1. 1

B. SITE #2 FS

Labeled with the patient's name, labeled "site #2 FS", and received fresh in the Operating Room for intraoperative frozen consultation and subsequently fixed in formalin is a 0.4 x 0.3 x 0.2 cm portion of soft tan tissue. The specimen is entirely submitted for frozen section diagnosis. Entirely submitted.

B1. Frozen section control for FS1 (specimen B) - 1

C. NCI RESEARCH PROTOCOL

Labeled with the patient's name, labeled "NCI research protocol", and received in a cassette labeled "C" is a 1.0 x 0.5 x 0.5 cm gray-tan soft tissue fragment. Entirely submitted.

C1. 2

D. NCI RESEARCH PROTOCOL

Labeled with the patient's name, labeled "NCI research protocol", and received in a cassette labeled "D" are two portions of soft pink-tan tissues measuring 0.7 and 0.5 cm, respectively, in greatest dimension. Entirely submitted.

D1. 2

E. NCI RESEARCH PROTOCOL

Labeled with the patient's name, labeled "NCI research protocol", and received in a cassette labeled "E" are two portions of soft pink-tan tissues ranging in size from 0.8 up to 1.0 cm in greatest dimension. Entirely submitted.

E1. 2

F. NCI RESEARCH PROTOCOL

[page 3 of 3]
PATIENT: [REDACTED]

PATH #:

Labeled with the patient's name, labeled "NCI research protocol", and received in a cassette labeled "F" are two portions of soft pink-tan tissues measuring 0.9 and 0.7 cm, respectively, in greatest dimension. Entirely submitted.
F1. 2

G. NCI RESEARCH PROTOCOL

Labeled with the patient's name, labeled "NCI research protocol", and received in a cassette labeled "G" are two fragments of soft pink-tan tissues each measuring 0.5 cm. greatest dimension. Entirely submitted.
G1. 2

H. NCI RESEARCH PROTOCOL

Labeled with the patient's name, labeled "NCI research protocol", and received in a cassette labeled "H" are two portions of soft pink-tan tissues measuring 0.6 and 0.5 cm, respectively, in greatest dimension. Entirely submitted.
H1. 2

I. BRAIN TUMOR

Labeled with the patient's name, labeled "brain tumor", and received in formalin are multiple fragmented pieces of pink-tan soft somewhat friable tissues together measuring 1.0 x 1.0 x 0.5 cm in total aggregate. Entirely submitted.
I1. Multiple

J. SITE #3

Labeled with the patient's name, labeled "site #3", and received in formalin is a 0.4 x 0.3 x 0.2 cm soft tan tissue fragment. Entirely submitted.
J1. 1

K. BRAIN TUMOR

Labeled with the patient's name, labeled "brain tumor", and received in formalin are two portions of friable, gray-tan soft focally hemorrhagic brain tissue. Tissues are serially sectioned and entirely submitted.
K1. 6

OPERATIVE CALL

OPERATIVE CONSULTATION (FROZEN):

B. SITE #2, FSA AND TPA:

- High grade glioma, favor glioblastoma multiforme

If this report includes immunohistochemical test results, please note the following:

Numerous immunohistochemical tests were developed and their performance characteristics determined by the Department of Pathology and Laboratory Medicine. Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
[REDACTED]

Source: NCI Genomic Data Commons file 4bd5dc6f-1c2d-4f36-b2ff-833fb3383867 (TCGA-28-1760.9B40D6A7-43EE-4267-8290-C4D8B3876FDF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).